Somatic mutation profile of tumor specimen C3L-05334-54 (aliquot CPT0303320002) from CPTAC case C3L-05334, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 38.1 years (13,916 days).
Specimen C3L-05334-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49e35903-6763-4675-af72-3628778067d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05334-51 (Buccal Cell Normal), aliquot CPT0303440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f133d358-28f2-43aa-a759-33e7a2615ff2

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DLC1 | c.1646G>A p.R549Q (on ENST00000276297 / NM_001348081.2; = p.R112Q on NM_006094.5) | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1196719927; called by muse, mutect2, varscan2
- CSKMT | c.717_718dup p.H240Lfs*35 | Frame Shift Ins (INS) | VAF 11/61 reads (18%) | called by mutect2, pindel, varscan2
